FM case AD9563 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/52ca6a95-a440-4ef0-b5b1-c5dd543e131a

Male, 56.8 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
